RC case RC-B56Q — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/69e1924a-0cee-48f8-9305-8907b9698fbe

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1946; Vital status: Dead; Days to death: 468 days (1.3 years); Year of death: 2016; Cause of death: Cancer Related.

Diagnoses (3)
1. Extranodal NK/T-cell lymphoma, nasal type (the primary disease): ICD-O-3 morphology code: 9719/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Abdomen, NOS; Classification of tumor: primary; Age at diagnosis: 69.4 years (25,332 days); Year of diagnosis: 2015; Method of diagnosis: Biopsy; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High Risk; Sites of involvement: Lymph node, NOS / Bone, NOS / Liver / Pericardium / Skin / Mesentery / Peritoneum, NOS.
   Pathology details: Bone marrow malignant cells: No; Greatest tumor dimension: 2.7 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Asparaginase + Dexamethasone + Etoposide + Ifosfamide + Methotrexate; Initial disease status: Initial Diagnosis; Regimen or line of therapy: SMILE; Days to treatment start: 45 days; Days to treatment end: 93 days; Number of cycles: 3; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Days to treatment start: 128 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Other; Therapeutic agents: Other; Initial disease status: Progressive Disease; Days to treatment start: 343 days; Days to treatment end: 367 days (1.0 years); Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Initial disease status: Progressive Disease; Days to treatment start: 382 days (1.0 years); Days to treatment end: 445 days (1.2 years); Reason treatment ended: Other; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Other; Initial disease status: Progressive Disease; Days to treatment start: 412 days (1.1 years); Days to treatment end: 426 days (1.2 years); Reason treatment ended: Other; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Recurrence (histology not recorded by GDC). Age at diagnosis: 70.3 years (25,661 days); Days to diagnosis: 329 days.
3. Progression (histology not recorded by GDC). Age at diagnosis: 70.4 years (25,705 days); Days to diagnosis: 373 days (1.0 years).

Follow-up (5 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 90.
- Days to follow up: 113 days; Disease response: Tumor Free.
- Day 329 (recurrence): Progression or recurrence: Yes; Days to recurrence: 329 days.
- Day 373 (progression): Progression or recurrence: Yes; Days to progression: 373 days (1.0 years).
- Day 468 (end of treatment course 1): Imaging type: PET; Imaging result: Negative.

Molecular and laboratory tests
- Epstein-Barr Virus: Positive [Test analyte type: DNA].
- Epstein-Barr Virus (ISH): Positive.
- Lactate Dehydrogenase 342 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Atrial Fibrillation.
- Timepoint category: Initial Diagnosis; Weight: 57.6 kg; Height: 162 cm; BMI: 21.9.
- Timepoint category: Prior to Diagnosis; Risk factors: Skin Rash / Epstein-Barr Virus.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B56Q-NB1-B: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B56Q-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B56Q-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 64; Percent tumor nuclei: 64; Percent normal cells: 28; Percent necrosis: 0; Percent stromal cells: 8; Percent lymphocyte infiltration: 28; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
